Somatic mutation profile of tumor specimen C3L-01952-01 (aliquot CPT0093070009) from CPTAC case C3L-01952, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 50.7 years (18,518 days).
Specimen C3L-01952-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fba1487b-4fef-452d-acac-8c54d1314170.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01952-31 (Blood Derived Normal), aliquot CPT0092580002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/633ea735-6ab0-4483-8494-2157d798a3e1

The open-access MAF lists 49 somatic variants for this specimen: 38 protein-altering or splice-affecting, 7 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 7, Intron 4, Frame Shift Del 4, In Frame Del 3, Nonsense Mutation 2, In Frame Ins 1, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKAP9 | c.7069T>A p.C2357S (on ENST00000359028; = p.C2333S on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/204 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.738); catalogued as rs931832401; called by muse, mutect2, varscan2
- CACNA1E | c.5947A>G p.I1983V | Missense Mutation (SNP) | VAF 41/261 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs1558400266, COSV100706041; called by muse, mutect2, varscan2
- DCAF4L2 | c.967A>C p.N323H | Missense Mutation (SNP) | VAF 56/185 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV60482958; called by muse, mutect2, varscan2
- FHL5 | c.38C>T p.A13V | Missense Mutation (SNP) | VAF 44/338 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs370135459; called by muse, mutect2, varscan2
- FRY | c.8461G>A p.E2821K | Missense Mutation (SNP) | VAF 81/510 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs746295815, COSV66569995; called by muse, mutect2, varscan2
- JAKMIP3 | c.25C>T p.R9W | Missense Mutation (SNP) | VAF 25/180 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs768454996, COSV100060145; called by muse, mutect2, varscan2
- NCOA6 | c.5305G>T p.D1769Y | Missense Mutation (SNP) | VAF 44/259 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.594); catalogued as COSV62864548; called by muse, mutect2, varscan2
- PRAM1 | c.1052G>A p.R351Q | Missense Mutation (SNP) | VAF 43/240 reads (18%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs762103173, COSV99725415; called by muse, mutect2, varscan2
- RTL1 | c.2323G>A p.V775M | Missense Mutation (SNP) | VAF 45/317 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.379); catalogued as rs775618332, COSV66016358, COSV99062590; called by muse, mutect2, varscan2
- TACR2 | c.1022C>T p.T341M | Missense Mutation (SNP) | VAF 34/234 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.27); catalogued as rs149794645, COSV53857450, COSV53861043; called by muse, mutect2, varscan2
- TPH2 | c.19_21del p.M7del | In Frame Del (DEL) | VAF 90/554 reads (16%) | catalogued as rs41265613; called by pindel, varscan2
- AFG3L2 | c.2340C>A p.N780K | Missense Mutation (SNP) | VAF 88/430 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- BICRA | c.1054del p.Q352Sfs*15 | Frame Shift Del (DEL) | VAF 42/219 reads (19%) | called by mutect2, pindel, varscan2
- CCDC183 | c.421_423del p.E141del | In Frame Del (DEL) | VAF 12/90 reads (13%) | called by pindel, varscan2
- CCDC186 | c.299del p.N100Ifs*16 | Frame Shift Del (DEL) | VAF 52/304 reads (17%) | called by mutect2, pindel, varscan2
- CDC27 | c.361_363del p.L121del | In Frame Del (DEL) | VAF 24/100 reads (24%) | called by pindel, varscan2
- CRX | c.61C>T p.P21S | Missense Mutation (SNP) | VAF 71/453 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- FA2H | c.19C>T p.P7S | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); called by muse, mutect2
- GARS1 | c.1871del p.N624Tfs*15 | Frame Shift Del (DEL) | VAF 80/475 reads (17%) | called by mutect2, pindel, varscan2
- GATM | c.1159+4T>G | Splice Region (SNP) | VAF 17/300 reads (6%) | called by muse, mutect2
- GLYCTK | c.507_508insGTG p.D169_L170insV | In Frame Ins (INS) | VAF 68/298 reads (23%) | called by mutect2, pindel*, varscan2*
- HMMR | c.987A>T p.Q329H | Missense Mutation (SNP) | VAF 54/393 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- ISLR | c.844_847del p.S282Pfs*190 | Frame Shift Del (DEL) | VAF 20/176 reads (11%) | called by mutect2, pindel
- LRFN5 | c.2140C>A p.Q714K | Missense Mutation (SNP) | VAF 47/309 reads (15%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.292); called by muse, mutect2, varscan2
- MAGEA1 | c.807G>T p.R269S | Missense Mutation (SNP) | VAF 54/201 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- MEST | c.794G>C p.W265S | Missense Mutation (SNP) | VAF 39/345 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MTMR10 | c.418G>T p.D140Y | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- NME7 | c.1117A>G p.I373V | Missense Mutation (SNP) | VAF 26/214 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- OGN | c.338C>T p.A113V | Missense Mutation (SNP) | VAF 32/247 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- OR6S1 | c.214G>T p.E72* | Nonsense Mutation (SNP) | VAF 41/255 reads (16%) | called by muse, mutect2, varscan2
- PLXNA3 | c.1856T>G p.L619R | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PPFIA2 | c.1267-14_1267-1del p.X423_splice | Splice Site (DEL) | VAF 52/234 reads (22%) | called by mutect2, pindel
- QSER1 | c.955G>A p.V319I (on ENST00000399302; = p.V448I on NM_001076786.3) | Missense Mutation (SNP) | VAF 42/267 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SLC26A8 | c.73G>T p.V25F | Missense Mutation (SNP) | VAF 41/323 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- SRCAP | c.9017A>G p.K3006R | Missense Mutation (SNP) | VAF 36/359 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.757); called by muse, mutect2, varscan2
- SRSF6 | c.895T>C p.S299P | Missense Mutation (SNP) | VAF 29/241 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- TTLL3 | c.2297C>G p.S766C | Missense Mutation (SNP) | VAF 78/514 reads (15%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- UMPS | c.136C>T p.R46* | Nonsense Mutation (SNP) | VAF 15/86 reads (17%) | called by muse, mutect2, varscan2
- ITGB6 | c.183C>T p.T61= | Silent (SNP) | VAF 53/332 reads (16%) | called by muse, mutect2, varscan2
- NCOA6 | c.4650T>A p.P1550= | Silent (SNP) | VAF 56/362 reads (15%) | called by muse, mutect2, varscan2
- OR4Q3 | c.372G>C p.L124= | Silent (SNP) | VAF 41/406 reads (10%) | catalogued as COSV59179652; called by muse, mutect2, varscan2
- PLD5 | c.996G>A p.V332= (on ENST00000442594; = p.V270= on NM_001195811.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 42/260 reads (16%) | called by muse, mutect2, varscan2
- RNF19A | c.471T>C p.D157= | Silent (SNP) | VAF 10/289 reads (3%) | catalogued as rs1050299452; called by muse, mutect2
- TLR9 | c.1308C>T p.T436= | Silent (SNP) | VAF 9/61 reads (15%) | called by muse, mutect2, varscan2
- YJEFN3 | c.276C>T p.L92= | Silent (SNP) | VAF 26/197 reads (13%) | catalogued as rs771716830; called by muse, mutect2, varscan2
- DOCK4 | c.1066+14C>G | Intron (SNP) | VAF 68/509 reads (13%) | called by muse, mutect2, varscan2
- OPRM1 | c.1165-11157C>A | Intron (SNP) | VAF 69/314 reads (22%) | called by muse, mutect2, varscan2
- P4HA2 | c.1372-11T>A | Intron (SNP) | VAF 55/304 reads (18%) | called by muse, mutect2, varscan2
- SLC43A2 | c.1217+41C>T | Intron (SNP) | VAF 49/262 reads (19%) | called by muse, mutect2, varscan2
